Somatic mutation profile of tumor specimen TCGA-2J-AAB1-01A (aliquot TCGA-2J-AAB1-01A-11D-A40W-08) from TCGA case TCGA-2J-AAB1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.6 years (23,962 days).
Specimen TCGA-2J-AAB1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e23d2f5-fc86-4fe9-adaf-6bde04437d23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AAB1-10A (Blood Derived Normal), aliquot TCGA-2J-AAB1-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df2ffc90-5551-449a-97ba-d4653a5fb0b1

The open-access MAF lists 68 somatic variants for this specimen: 58 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 48, Silent 10, Frame Shift Ins 5, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 29/238 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs775791158, COSV99940809; called by muse, mutect2, varscan2
- ALOX15 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV99541338; called by muse, mutect2, varscan2
- APC | c.5474A>G p.D1825G | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1554086747, COSV99967046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.4321C>T p.R1441W | Missense Mutation (SNP) | VAF 163/901 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs773288022, COSV60894967; called by muse, mutect2, varscan2
- C19orf57 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 85/515 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs145142690; called by muse, mutect2, varscan2
- CACNA1H | c.2707C>A p.R903S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100671886, COSV62000629; called by muse, mutect2
- CACNA1H | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520721, COSV100671888; ClinVar: uncertain significance; called by muse, mutect2
- CHD6 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58563896; called by muse, mutect2, varscan2
- CRNN | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 192/1049 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV99664082; called by muse, mutect2, varscan2
- CUL4B | c.1671T>G p.N557K | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340372; called by muse, mutect2, varscan2
- DAW1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as rs759961104, COSV100006080; called by muse, mutect2, varscan2
- DCLRE1B | c.854T>G p.F285C | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100849774; called by muse, mutect2, varscan2
- DHX35 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 201/1044 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV99326702; called by muse, mutect2, varscan2
- DIO3 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1210716639, COSV100832092; called by muse, mutect2
- DNPEP | c.1447T>G p.L483V | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99815137; called by muse, mutect2, varscan2
- DOCK3 | c.5290C>T p.R1764* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV56528696; called by muse, mutect2, varscan2
- DPYD | c.312T>G p.I104M | Missense Mutation (SNP) | VAF 76/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749699298, COSV100031947; called by muse, mutect2, varscan2
- ELF3 | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 132/810 reads (16%) | catalogued as COSV100668701; called by muse, mutect2, varscan2
- EPC2 | c.2195A>G p.H732R | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.954); catalogued as COSV51543626; called by muse, mutect2, varscan2
- GBX1 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52547370; called by muse, mutect2
- GLI2 | c.1592C>T p.S531L (on ENST00000361492 / NM_001374353.1; = p.S548L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1418648944, COSV100082433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLRA1 | c.158A>T p.D53V | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99199519; called by muse, mutect2
- HNRNPLL | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 30/804 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99696505; called by muse, mutect2
- IGHV1-58 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 96/455 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782683680; called by muse, mutect2, varscan2
- KIF24 | c.3249G>C p.E1083D | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99903044; called by muse, mutect2
- KLHL40 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 142/333 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV55134914, COSV99825633; called by muse, mutect2, varscan2
- LRCH1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 125/653 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100243509; called by muse, mutect2, varscan2
- NEBL | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs776914197, COSV65802418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOC4L | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 114/666 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758550684, COSV100400064; called by muse, mutect2, varscan2
- OGT | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs1326442849, COSV65480952; called by muse, mutect2, varscan2
- OLFML2B | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54194598; called by muse, mutect2, varscan2
- OR4M1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 143/2258 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.081); catalogued as COSV100271103, COSV100271241; called by muse, mutect2
- OR51I2 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 98/566 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV58298068; called by muse, mutect2
- OR8J3 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 115/591 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.624); catalogued as COSV100040747; called by muse, mutect2, varscan2
- PCDH9 | c.3674C>T p.A1225V (on ENST00000377865 / NM_203487.3; = p.A1191V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100119708, COSV60527794; called by muse, mutect2, varscan2
- PLEK | c.940del p.L314Ffs*48 | Frame Shift Del (DEL) | VAF 90/581 reads (15%) | catalogued as rs1376039207, COSV52251539; called by mutect2, pindel, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 44/262 reads (17%) | catalogued as rs751873496; called by mutect2, varscan2
- RTN4RL1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs753662485, COSV58675781; called by muse, mutect2, varscan2
- SEMA5A | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 60/491 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369851619; called by muse, mutect2, varscan2
- SEZ6L | c.2194T>C p.F732L | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV99961801; called by muse, mutect2, varscan2
- SLC6A15 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 134/686 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1173837286, COSV57023032; called by muse, mutect2, varscan2
- STPG3 | c.370dup p.H124Pfs*35 | Frame Shift Ins (INS) | VAF 46/315 reads (15%) | catalogued as rs1264784455; called by mutect2, pindel, varscan2
- TANC1 | c.5351C>T p.T1784I | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV99713587; called by muse, mutect2, varscan2
- TGFBR2 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504421, CM064328, CM139809, COSV55448438, COSV55452463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM116 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702150; called by muse, mutect2, varscan2
- TPCN1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 135/817 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1169168475, COSV100136614; called by muse, mutect2, varscan2
- UBASH3B | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 202/1086 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99417406; called by muse, mutect2, varscan2
- UBASH3B | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99417410; called by muse, mutect2
- USP44 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.497); catalogued as COSV99311751; called by muse, mutect2, varscan2
- WDR37 | c.811C>A p.R271S | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99579529; called by muse, mutect2, varscan2
- ANKRD26 | c.2814dup p.E939Rfs*6 | Frame Shift Ins (INS) | VAF 22/157 reads (14%) | called by mutect2, pindel, varscan2
- EXPH5 | c.3556dup p.Q1186Pfs*5 | Frame Shift Ins (INS) | VAF 79/541 reads (15%) | called by mutect2, pindel, varscan2
- MBD6 | c.911_923del p.L304Pfs*69 | Frame Shift Del (DEL) | VAF 44/254 reads (17%) | called by mutect2, varscan2
- MUC5AC | c.14095dup p.E4699Gfs*90 | Frame Shift Ins (INS) | VAF 81/473 reads (17%) | called by mutect2, pindel, varscan2
- TNFRSF10B | c.974_984delinsAT p.L325_P328delinsH | In Frame Del (DEL) | VAF 49/445 reads (11%) | called by pindel, varscan2*
- TOP2A | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- ZNF114 | c.793A>C p.M265L | Missense Mutation (SNP) | VAF 14/453 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- ABCA4 | c.3945G>A p.Q1315= | Silent (SNP) | VAF 22/452 reads (5%) | catalogued as COSV100933097; called by muse, mutect2
- ANPEP | c.2538C>T p.S846= | Silent (SNP) | VAF 15/466 reads (3%) | called by muse, mutect2
- EIF2B5 | c.753T>C p.D251= (on ENST00000647909; = p.D243= on NM_003907.3) | Silent (SNP) | VAF 24/563 reads (4%) | catalogued as COSV99889168; called by muse, mutect2
- KLHL1 | c.702C>T p.S234= | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as rs766173867, COSV64780037; called by muse, mutect2, varscan2
- MOV10L1 | c.438C>T p.C146= | Silent (SNP) | VAF 55/315 reads (17%) | catalogued as rs757077590, COSV53169091; called by muse, mutect2, varscan2
- OR51I2 | c.309T>A p.L103= | Silent (SNP) | VAF 96/566 reads (17%) | catalogued as rs1564818398, COSV100413370; called by muse, mutect2
- PCDHA9 | c.1794C>T p.D598= | Silent (SNP) | VAF 84/426 reads (20%) | catalogued as rs781988221, COSV65334489; called by muse, varscan2
- PCDHA9 | c.1923C>T p.D641= | Silent (SNP) | VAF 58/420 reads (14%) | catalogued as COSV65326494, COSV65330142; called by muse, varscan2
- PDE11A | c.1293C>T p.I431= | Silent (SNP) | VAF 116/520 reads (22%) | catalogued as rs768545961, COSV53693030; called by muse, mutect2
- RNF207 | c.1890G>A p.R630= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV100658252; called by muse, mutect2, varscan2
